Surgical pathology report (de-identified scan), TCGA case TCGA-BQ-5875, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BQ-5875-01A (Primary Tumor).

[page 1 of 4]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Original Rep

Date of Amendment

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

with large left sided abdominal mass involving left kidney/spleen/colon.

Specimens Submitted:

1: SP: Left kidney

2: SP: Left tube and o

3: SP: Rt. tube & ovar

4: SP: Spleen

AMENDED DIAGNOSIS:

- 1) KIDNEY, LEFT, NEPHRECTOMY:
- RENAL CELL CARCINOMA, PAPILLARY TYPE WITH EXTENSIVE ONCOCYTIC (OXYPHILIC) CYTOLOGIC FEATURES.
- THE TUMOR GREATEST DIAMETER IS 13.0 CM.
- THE TUMOR EXTENDS THROUGH THE RENAL CAPSULE BUT IS CONFINED WITHIN GEROTA'S FASCIA.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- THE ADRENAL GLAND IS UNREMARKABLE AND NOT INVOLVED BY TUMOR.
- 2) FALLOPIAN TUBE AND OVARY, LEFT, RESECTION:
- UNREMARKABLE OVARY AND FALLOPIAN TUBE WITH PARATUBAL CYSTS.
- 3) FALLOPIAN TUBE AND OVARY, RIGHT, RESECTION:
- UNREMARKABLE OVARY AND FALLOPIAN TUBE WITH PARATUBAL CYSTS.
- 4) SPLEEN, SPLENECTOMY:
- SPLEEN WITH HEMORRHAGIC AND NON-CASEATING GRANULOMAS.
- NO TUMOR SEEN.

Note:

This document represents an amended version of the surgical pathology report originally issued on [REDACTED]. That report, although, retained in the clinical chart for record purposes, is superseded by the present document. The amendment consists of the following change:

ORIGINAL REPORT:

Gross Description:

Part 1

The specimen is inked and on cut section it reveals the kidney to be replaced almost entirely by multiple nodules of tan-yellow, partially cystic tumor occupying the whole kidney, measuring approximately 13.0 x 9.0 x 6.0 cm. The tumor grossly appears to be confined to the renal capsule. The tumor surface shows fine papillary fronts. TPS is submitted. Photographs taken. Representative sections are submitted.

AMENDED REPORT:

[page 2 of 4]
Gross Description:
Part 1

The specimen is inked and on cut section it reveals the kidney to be replaced almost entirely by multiple nodules of tan-yellow, partially cystic, hemorrhagic tumor occupying the whole kidney, measuring approximately 13.0 x 9.0 x 6.0 cm. The tumor grossly abuts the adrenal gland (6.0 x 2.0 x 1.5 cm). The tumor grossly appears to be confined to the renal capsule. The tumor surface show fine papillary fronts. TPS is submitted. Photographs taken. Representative sections are submitted.

add on:

Summary of Sections:

ATA – Additional tumor with adrenal sections

The responsible clinician has been notified.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result	Special Stain	Comment
	RECUT	
	RECUT	
	RECUT	
	RECUT	

1) The specimen is received fresh for frozen section diagnosis, labeled, "Left kidney". It consists of a 1190 grams nephrectomy specimen (23.0 x 13.0 x 9.0 cm) with attached segment of ureter (1.5 cm in length and 0.4 cm in diameter), and segment of renal vein (3.0 cm in length and 0.3 cm in diameter). The perirenal fat is minimal. The specimen is inked and on cut section it reveals the kidney to be replaced almost entirely by multiple nodules of tan-yellow, partially cystic, hemorrhagic tumor occupying the whole kidney, measuring approximately 13.0 x 9.0 x 6.0 cm. The tumor grossly abuts the adrenal gland (6.0 x 2.0 x 1.5 cm). The tumor grossly appears to be confined to the renal capsule. The tumor surface show fine papillary fronts. TPS is submitted. Photographs taken. Representative sections are submitted.

Summary of Sections:

FSC – frozen section control

UV – ureteral and vascular margin

TC – tumor section with the capsule

C – cystic areas of the tumor

TRP – tumor with the adjacent renal parenchyma

ATA – Additional tumor with adrenal sections

2). The specimen is received fresh for frozen section consultation labeled, "Left tube and ovary" and consists a segment of fallopian tube with fimbriated end measuring 4.8 cm in length x 0.3 cm in diameter. The serosa is tan-pink, smooth and unremarkable. The fallopian tube is serially cross-sectioned to reveal unremarkable cut surface with a 0.1 cm lumen. There are numerous paratubal cysts identified ranging in size from 0.1 to 0.8 cm in greatest dimension. The attached ovary is tan-white, smooth and firm. Cut surface is unremarkable and except for numerous corpora albicantia. Representative sections are submitted for frozen and permanent sections.

Summary of sections:

[page 3 of 4]
FSC-frozen section control
LTO-left tube and ovary, representative sections

3). The specimen is received in fresh for frozen section consultation labeled, "Right tube and ovary" and consists a segment of fallopian tube with fimbriated end measuring 6.5 cm in length by a 0.4 cm in diameter. The serosa is tan-pink and smooth with some minute paratubal cysts each measuring less than 0.1 cm in diameter. The fallopian tube is serially cross-sectioned to reveal unremarkable cut surface with a 0.1 cm lumen. The attached ovary measures 2 x 2 x 1.5 cm. External surface is tan-white with a 1 x 0.8 x 0.3 cm cyst. The external surface is inked in blue. Cut surface is light tan, unremarkable. Corpora albicantia are identified. Representative sections are submitted for frozen and permanent sections.

Summary of sections:
FSC-frozen section control
RTO-right tube and ovary, representative sections

4) The specimen is received fresh, labeled, "Spleen". It consists of a 120 grams spleen (11.0 x 7.0 x 5.0 cm). The hilum reveals no lymph nodes. The capsule appears to be partially eroded with hemorrhagic surface it. Cut sections reveal a 4.5 cm triangular infarction. The remaining spleen parenchyma appears unremarkable. Representative sections are submitted.

Summary of Sections:
H – hilum section
IF – infarction area
C – capsular surface
U – unremarkable parenchyma

Summary of Sections:

Part 1: SP: Left kidney

Block	Sect. Site	PCs
5	ATA	5
5	C	5
1	FSC	1
6	TC	6
5	TRP	5
1	UV	3

Part 2: SP: Left tube and ovary

Block	Sect. Site	PCs
1	FSC	1
1	LTO	4

Part 3: SP: Rt. tube & ovary

Block	Sect. Site	PCs
1	FSC	1
1	RTO	4

Part 4: SP: Spleen

Block	Sect. Site	PCs
1	C	1
1	H	2
1	IF	1
1	U	1

[page 4 of 4]
Amendments

Original Diagnosis:

- 1) KIDNEY, LEFT, NEPHRECTOMY:
- RENAL CELL CARCINOMA, PAPILLARY TYPE WITH EXTENSIVE ONCOCYTIC (OXYPHILIC) CYTOLOGIC FEATURES.
- THE TUMOR GREATEST DIAMETER IS 13.0 CM.
- THE TUMOR EXTENDS THROUGH THE RENAL CAPSULE BUT IS CONFINED WITHIN GEROTA'S FASCIA.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- THE ADRENAL GLAND IS NOT SUBMITTED.
- 2) FALLOPIAN TUBE AND OVARY, LEFT, RESECTION:
- UNREMARKABLE OVARY AND FALLOPIAN TUBE WITH PARATUBAL CYSTS.
- 3) FALLOPIAN TUBE AND OVARY, RIGHT, RESECTION:
- UNREMARKABLE OVARY AND FALLOPIAN TUBE WITH PARATUBAL CYSTS
- 4) SPLEEN, SPLENECTOMY:
- SPLEEN WITH HEMORRHAGIC AND NON-CASEATING GRANULOMAS.
- NO TUMOR SEEN.

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL CARCINOMA
PERMANENT DIAGNOSIS: SEE FINAL.
- 2) FROZEN SECTION DIAGNOSIS: PARATUBAL CYST.
PERMANENT DIAGNOSIS: SAME.
- 3) FROZEN SECTION DIAGNOSIS: BENIGN
PERMANENT DIAGNOSIS: SAME.

Source: NCI Genomic Data Commons file 0b40c583-d5b8-4a18-906e-eaf50176f9c1 (TCGA-BQ-5875.46221377-96F4-4437-AD63-23FF63D64FB7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).